Somatic mutation profile of tumor specimen C3L-01032-01 (aliquot CPT0170510026) from CPTAC case C3L-01032, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.8 years (19,276 days).
Specimen C3L-01032-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a9b3c9b-3ff5-407c-95e4-056906c18c4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01032-31 (Blood Derived Normal), aliquot CPT0167270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7704860f-b411-4fde-a4de-9f54361440a5

The open-access MAF lists 96 somatic variants for this specimen: 69 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 23, Frame Shift Del 5, Splice Site 3, Splice Region 2, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1, In Frame Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.4894_4895del p.S1632Yfs*6 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | catalogued as rs397507748; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 128/368 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 271/760 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP14 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs1211723259, COSV57631271; called by muse, mutect2, varscan2
- ALS2CL | c.2736del p.N913Tfs*26 | Frame Shift Del (DEL) | VAF 29/292 reads (10%) | catalogued as COSV59671270; called by pindel, varscan2
- ARHGEF26 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV62852843; called by muse, mutect2, varscan2
- CUX2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 177/343 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs376298955; called by muse, mutect2, varscan2
- DMAP1 | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.177); catalogued as rs1347980099; called by muse, mutect2
- FBXO34 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs1345251564; called by muse, mutect2
- GLI4 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 149/691 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100391048; called by muse, mutect2, varscan2
- GPR17 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 96/378 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs755635107, COSV55756400; called by muse, mutect2, varscan2
- GTF2H4 | c.1271A>C p.H424P | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV52559148; called by muse, mutect2
- IGDCC3 | c.1453G>C p.V485L | Missense Mutation (SNP) | VAF 118/403 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs552951892; called by muse, mutect2, varscan2
- KIDINS220 | c.3991G>A p.E1331K | Missense Mutation (SNP) | VAF 15/366 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV56752111; called by muse, mutect2
- LCN8 | c.517-5C>T | Splice Region (SNP) | VAF 62/225 reads (28%) | catalogued as rs1042605820; called by muse, mutect2, varscan2
- LTF | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV99210583; called by muse, mutect2, varscan2
- NF2 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100098489; called by muse, mutect2, varscan2
- OFD1 | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs752818939; called by muse, mutect2, varscan2
- OR51A7 | c.718T>C p.C240R | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1421717037; called by muse, mutect2
- PCDH15 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 165/777 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs573043647, COSV57311329, COSV57330716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB7 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); catalogued as rs1372083895; called by muse, mutect2, varscan2
- PI4KA | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs1478035031; called by muse, mutect2
- PLEKHM1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 141/577 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs763911008, COSV101378669; called by muse, mutect2, varscan2
- RGS1 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66506294; called by muse, mutect2, varscan2
- SEC61A2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 38/498 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV100036454; called by muse, mutect2
- WDFY4 | c.5804G>A p.G1935D | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1189664648; called by muse, mutect2, varscan2
- ZBTB11 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57244586; called by muse, mutect2, varscan2
- ZNF518A | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs782439291; called by muse, mutect2
- ABCC1 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 61/337 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ABCC3 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 84/504 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACAN | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACTL7B | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ADAM10 | c.736-1G>C p.X246_splice | Splice Site (SNP) | VAF 50/331 reads (15%) | called by muse, mutect2, varscan2
- ADGRL3 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 85/630 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANGPTL6 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- C3orf38 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 46/391 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CCDC159 | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); called by muse, mutect2
- CDCA2 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FAM71E2 | c.2010G>C p.K670N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- FOXP3 | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GUSBP10 | n.370G>T | Splice Region (SNP) | VAF 24/168 reads (14%) | called by muse, varscan2
- HSD11B1L | c.61A>G p.N21D | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IGSF9B | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- INSYN2B | c.713_719del p.D238Vfs*8 | Frame Shift Del (DEL) | VAF 22/168 reads (13%) | called by mutect2, pindel, varscan2
- ITM2C | c.12del p.S5Afs*32 | Frame Shift Del (DEL) | VAF 18/129 reads (14%) | called by mutect2, pindel, varscan2
- LRRTM4 | c.1484C>A p.T495N | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- MUC16 | c.7192G>C p.G2398R | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO15A | c.2169G>T p.E723D | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- NF2 | c.835A>T p.K279* | Nonsense Mutation (SNP) | VAF 54/293 reads (18%) | called by muse, mutect2, varscan2
- NR0B1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 153/869 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PIH1D1 | c.517T>G p.S173A | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- PLA2G4F | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- POU2F2 | c.129+2T>G p.X43_splice | Splice Site (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- PRR33 | c.926_937del p.V309_P312del | In Frame Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- RBM20 | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNASE13 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPL3 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- RYR3 | c.2953A>G p.K985E | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SON | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 139/736 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- SOST | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 96/410 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- SRPK3 | c.1147+1G>T p.X383_splice | Splice Site (SNP) | VAF 59/201 reads (29%) | called by muse, mutect2, varscan2
- TBC1D31 | c.3129_3131delinsAA p.R1044Kfs*50 | Frame Shift Del (DEL) | VAF 19/220 reads (9%) | called by pindel, varscan2*
- TET3 | c.3034_3035insC p.K1012Tfs*41 | Frame Shift Ins (INS) | VAF 41/217 reads (19%) | called by mutect2, pindel, varscan2
- TIAM1 | c.4706C>G p.A1569G | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2
- TOPAZ1 | c.3125G>C p.R1042P | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC2 | c.1282T>A p.S428T | Missense Mutation (SNP) | VAF 75/478 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC13C | c.4208A>C p.Q1403P | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VIPAS39 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 23/867 reads (3%) | called by muse, mutect2
- ZNF208 | c.2808G>T p.K936N | Missense Mutation (SNP) | VAF 79/438 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CELF5 | c.822C>T p.P274= | Silent (SNP) | VAF 16/511 reads (3%) | called by muse, mutect2
- FABP1 | c.75G>A p.P25= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs145520267; called by muse, mutect2, varscan2
- FAM47B | c.690T>A p.T230= | Silent (SNP) | VAF 70/520 reads (13%) | called by muse, mutect2, varscan2
- GRIN2C | c.769C>T p.L257= | Silent (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- GUCA1C | c.483A>G p.K161= | Silent (SNP) | VAF 56/215 reads (26%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1764G>A p.S588= | Silent (SNP) | VAF 41/216 reads (19%) | catalogued as rs745388879, COSV56263381; called by muse, mutect2, varscan2
- KCNC1 | c.1425C>T p.V475= | Silent (SNP) | VAF 75/289 reads (26%) | catalogued as rs755628813, COSV56395720; called by muse, mutect2, varscan2
- KCNN3 | c.90G>A p.Q30= | Silent (SNP) | VAF 72/385 reads (19%) | catalogued as rs1360893418; called by muse, varscan2
- LRRTM4 | c.144G>A p.E48= | Silent (SNP) | VAF 71/407 reads (17%) | catalogued as rs1371045223; called by muse, mutect2, varscan2
- NMB | c.6C>G p.A2= | Silent (SNP) | VAF 81/401 reads (20%) | called by muse, mutect2, varscan2
- OR6Y1 | c.669C>T p.Y223= | Silent (SNP) | VAF 81/377 reads (21%) | catalogued as rs537972026, COSV56928838; called by muse, mutect2, varscan2
- RBM11 | c.81C>T p.Y27= | Silent (SNP) | VAF 11/308 reads (4%) | catalogued as COSV68748311; called by muse, mutect2
- ROBO4 | c.1011G>A p.V337= | Silent (SNP) | VAF 11/218 reads (5%) | called by muse, mutect2
- SDK2 | c.4140C>A p.R1380= | Silent (SNP) | VAF 73/205 reads (36%) | catalogued as rs1163126033; called by muse, mutect2, varscan2
- SEMA3F | c.2103C>T p.A701= | Silent (SNP) | VAF 34/257 reads (13%) | catalogued as rs775821212; called by muse, mutect2, varscan2
- STXBP6 | c.246C>T p.L82= | Silent (SNP) | VAF 53/284 reads (19%) | catalogued as rs374634547; called by muse, mutect2, varscan2
- TRBJ2-6 | c.52C>T p.L18= | Silent (SNP) | VAF 14/292 reads (5%) | catalogued as rs1280183881; called by muse, mutect2
- TRBV20OR9-2 | c.315A>T p.P105= | Silent (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- TSC22D2 | c.1683A>G p.L561= | Silent (SNP) | VAF 84/504 reads (17%) | catalogued as rs753814825; called by muse, mutect2, varscan2
- TSGA10IP | c.15C>G p.T5= | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as COSV101598412; called by muse, mutect2, varscan2
- TTBK1 | c.237C>T p.A79= | Silent (SNP) | VAF 48/332 reads (14%) | catalogued as rs774455336; called by muse, mutect2, varscan2
- UNC45B | c.774G>A p.R258= | Silent (SNP) | VAF 31/187 reads (17%) | called by muse, mutect2, varscan2
- VN1R4 | c.540T>G p.R180= | Silent (SNP) | VAF 36/199 reads (18%) | called by muse, mutect2, varscan2
- ECSIT | c.*25C>T | 3'UTR (SNP) | VAF 66/256 reads (26%) | called by muse, mutect2, varscan2
- MPI | c.844+74_844+76del | Intron (DEL) | VAF 49/276 reads (18%) | catalogued as rs1440664472; called by mutect2, pindel, varscan2
- RSAD1 | c.474+74C>T | Intron (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- UBTFL2 | n.371T>C | RNA (SNP) | VAF 142/1152 reads (12%) | catalogued as rs772588693; called by muse, mutect2, varscan2
